CCDI case PBCMFT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/085bda4a-1e70-4fcf-b718-28bcfa9694ad

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 13.6 years (4,970 days).

Biospecimens (3 samples)
- Sample 0DVPN0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPP2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
